Somatic mutation profile of tumor specimen TCGA-TQ-A7RH-01A (aliquot TCGA-TQ-A7RH-01A-12D-A34A-08) from TCGA case TCGA-TQ-A7RH, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.8 years (14,524 days).
Specimen TCGA-TQ-A7RH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 563a8b70-91b4-45f5-bc33-6b63842c6316.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RH-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RH-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/637b7093-d7a7-49ee-9467-2f55dbd492a4

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 4, 5'Flank 2, Splice Region 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 48/115 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 87/105 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6080T>C p.L2027P | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64882217; called by muse, mutect2, varscan2
- CCDC153 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs768602098, COSV100501276; called by muse, mutect2, varscan2
- CCR8 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100413046; called by muse, mutect2, varscan2
- CDC123 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as COSV99826809; called by muse, mutect2
- CENPJ | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101121486; called by muse, mutect2
- COL4A6 | c.3002C>A p.P1001H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV100563766; called by muse, mutect2, varscan2
- CTSB | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100565833; called by muse, mutect2, varscan2
- CYHR1 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.661); catalogued as COSV100023687; called by muse, mutect2, varscan2
- DCLRE1A | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 69/191 reads (36%) | catalogued as COSV100800290; called by muse, mutect2, varscan2
- FBXL13 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 42/208 reads (20%) | catalogued as rs202190502, COSV100500983; called by muse, mutect2, varscan2
- FLOT2 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as rs187973207, COSV67529684; called by muse, mutect2, varscan2
- IKZF1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1184423158, COSV58786188, COSV58792045; called by muse, mutect2, varscan2
- IP6K2 | c.1043A>G p.D348G | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.185); catalogued as COSV53664446; called by muse, mutect2, varscan2
- KIAA1210 | c.2930C>T p.S977F | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.19); PolyPhen benign (0.383); catalogued as COSV101274029, COSV68176417; called by muse, mutect2, varscan2
- NOL8 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371384399, COSV100694499; called by muse, mutect2, varscan2
- OR14K1 | c.116T>C p.M39T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99315053; called by muse, mutect2, varscan2
- OR2F2 | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68833372; called by muse, mutect2
- OR5K1 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745449878, COSV100220906, COSV60303500; called by muse, mutect2
- SEL1L3 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1229331983, COSV53545257; called by muse, mutect2
- SEMA4F | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs563916347, COSV100335882; called by muse, mutect2, varscan2
- SLF2 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99488811; called by muse, mutect2
- SSPOP | n.5915G>A | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as rs569985812, COSV100022296; called by muse, mutect2, varscan2
- TMEM26 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs760815670, COSV53263853; called by muse, mutect2, varscan2
- ZNF668 | c.1457G>A p.C486Y | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.087); catalogued as COSV100336557; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by mutect2, varscan2
- NLRP12 | c.765_775del p.M255Ifs*16 | Frame Shift Del (DEL) | VAF 19/27 reads (70%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.858_878del p.A287_A293del | In Frame Del (DEL) | VAF 28/122 reads (23%) | called by mutect2, varscan2
- ABCC12 | c.3954T>C p.V1318= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV100252412; called by muse, mutect2, varscan2
- ADPRHL1 | c.195C>T p.T65= | Silent (SNP) | VAF 49/69 reads (71%) | catalogued as rs369993693; called by muse, mutect2, varscan2
- AOC3 | c.654G>A p.L218= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV99520070; called by muse, mutect2, varscan2
- CLSTN2 | c.2427C>T p.P809= | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as COSV101515628, COSV71719768; called by muse, mutect2
- LAMA2 | c.567G>A p.P189= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs746692025, COSV101370279; called by muse, mutect2, varscan2
- PRAG1 | c.2709C>T p.G903= | Silent (SNP) | VAF 15/240 reads (6%) | catalogued as rs765994600, COSV100422027; called by muse, mutect2
- ZZEF1 | c.3915G>T p.G1305= | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as COSV101067675; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847241 C>A | 5'Flank (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- UNK | chr17:75784785 del T | 5'Flank (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
